Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0M6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0M6-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: ADNEXUM, RIGHT, RIGHT SALPINGO-OOPHORECTOMY -

- A. OVARY WITH SMALL INCLUSION CYST.
- B. UNREMARKABLE FALLOPIAN TUBE.

PART 2: ADNEXUM, LEFT, LEFT SALPINGO-OOPHORECTOMY -

- A. OVARY WITH METASTATIC ADENOCARCINOMA.
- B. UNREMARKABLE FALLOPIAN TUBE.

PART 3: UTERUS (276 GRAMS), TOTAL ABDOMINAL HYSTERECTOMY -

- A. POORLY-DIFFERENTIATED ADENOCARCINOMA OF ENDOMETRIUM, PAPILLARY SEROUS TYPE, FIGO GRADE 3.
- B. NEOPLASM INVADDES 100% OF MYOMETRIUM POSTERIORLY WITHOUT SEROSAL EXTENSION.
- C. NEOPLASM INVOLVES 100% OF ENDOMETRIAL SURFACE.
- D. LYMPHOVASCULAR INVASION IDENTIFIED.
- E. PATHOLOGIC STAGE pT3a pN1 pMX, FIGO STAGE 3C.
- F. LEIOMYOMA, 4.5 CM.

PART 4: CERVIX, TOTAL ABDOMINAL HYSTERECTOMY -

- A. PAPILLARY SEROUS ADENOCARCINOMA EXTENDING INTO ENDOCERVICAL GLANDS AND DEEPLY INVOLVING CERVICAL STROMA.
- B. NEOPLASM EXTENDS TO DEEP MARGIN OF RESECTION POSTERIORLY.
- C. ECTOCERVICAL MARGIN OF RESECTION APPEARS FREE OF NEOPLASM.

PART 5: OMENTUM, OMENTECTOMY -

UNREMARKABLE ADIPOSE TISSUE, NO NEOPLASM IDENTIFIED.

PART 6: ABDOMINAL PERITONEUM, LEFT, BIOPSY A -

UNREMARKABLE ADIPOSE TISSUE, NO NEOPLASM IDENTIFIED.

ICD-0-3

PART 7: ABDOMINAL PERITONEUM, LEFT, BIOPSY B -

SOFT TISSUE, NO NEOPLASM IDENTIFIED.

Adenocarcinoma, serous, NOS 8441/3

PART 8: PELVIC PERITONEUM, LEFT, BIOPSY -

SOFT TISSUE, NO NEOPLASM IDENTIFIED.

Site: Endometrium C54.1
pw 5/3/11

PART 9: ANTERIOR CUL-DE-SAC, BIOPSY -

FIBROADIPOSE TISSUE, NO NEOPLASM IDENTIFIED.

PART 10: PELVIC PERITONEUM, RIGHT, BIOPSY -

SOFT TISSUE, NO NEOPLASM IDENTIFIED.

PART 11: ABDOMINAL PERITONEUM, RIGHT, BIOPSY A -

SOFT TISSUE, NO NEOPLASM IDENTIFIED.

PART 12: ABDOMINAL PERITONEUM, RIGHT, BIOPSY B -

SOFT TISSUE, NO NEOPLASM IDENTIFIED.

PART 13: LYMPH NODE, LEFT PELVIC, DISSECTION -

TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

PART 14: LYMPH NODES, LEFT PELVIC, DISSECTION -

TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

PART 15: LYMPH NODES, LEFT COMMON ILIAC, DISSECTION -

TWO OF FOUR LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (2/4), ONE WITH EXTRACAPSULAR EXTENSION.

PART 16: LYMPH NODES, LEFT PERIAORTIC, DISSECTION -

ONE OF THREE LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (1/3).

PART 17: LYMPH NODES, RIGHT PELVIC, DISSECTION -

TWO OF SEVEN LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (2/7), ONE WITH EXTRACAPSULAR EXTENSION.

PART 18: LYMPH NODES, RIGHT PELVIC, DISSECTION -

ONE LYMPH NODE POSITIVE FOR METASTATIC CARCINOMA (1/1).

PART 19: LYMPH NODES, RIGHT PERIAORTIC, DISSECTION -

TWO OF TWO LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (2/2).

PART 20: APPENDIX, APPENDECTOMY -

FIBROUS OBLITERATION OF DISTAL APPENDICEAL LUMEN. NO NEOPLASM IDENTIFIED.

[page 2 of 2]
CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Serous adenocarcinoma

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Poorly differentiated (FIGO 3)

ARCHITECTURAL GRADE: Poorly differentiated

NUCLEAR GRADE: Grade 3

TUMOR SIZE: Maximum dimension: 6.5 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 100 %, Posterior endomyometrium: 100 %

DEPTH OF INVASION:** Greater than 1/2 thickness of myometrium

STRUCTURES INVOLVED: Endocervical glands, Cervical stroma, Adnexa

ANGIOLYMPHATIC INVASION: Yes

OTHER: (epithelial, smooth muscle, others), Leiomyoma

LYMPH NODES POSITIVE: Number of lymph nodes positive:: 8

LYMPH NODES EXAMINED: Total number of lymph nodes examined: 21

LYMPH NODE GROUPS INVOLVED: Pelvic lymph nodes, Right, Common iliac lymph nodes, Left, Para-aortic lymph nodes, Right, Para-aortic lymph nodes, Left

EXTRANODAL EXTENSION: Yes

T STAGE, PATHOLOGIC: pT3a

N STAGE, PATHOLOGIC: pN1

M STAGE, PATHOLOGIC: pMX

FIGO STAGE: IIIC

Source: NCI Genomic Data Commons file 001d42e3-081f-4bc6-89f2-7e7a54b85f5f (TCGA-BG-A0M6.39EC3673-5B31-403B-8328-9DEA5FF7CD1A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).